Gene-level copy-number profile of tumor specimen TCGA-IH-A3EA-01A from TCGA case TCGA-IH-A3EA, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Nodular melanoma; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 62.2 years (22,718 days).
Specimen TCGA-IH-A3EA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.aafea788-004a-4f57-b28f-2e4c4fab0b65.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-IH-A3EA-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/04737a64-4a90-4919-9057-3c27795fe795

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 6,538; copy number 2: 47,033; copy number 3: 3,752; copy number 4: 1,585; copy number 5: 912.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-IH-A3EA-01A-11D-A20B-01): tumor purity 0.75, ploidy 2.06, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 912 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:2,245,718–30,364,280, 701 genes, copy number 5 (broad region; genes not listed).
- chr6:44,273,194–44,378,957, 1 gene, copy number 5 (within-gene range 4–5): AL353588.1.
- chr6:44,342,650–58,438,364, 210 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4,117. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
